Surgical pathology report (de-identified scan), TCGA case TCGA-28-1751, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1751-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

- A. BRAIN, LEFT FRONTAL, EXCISIONAL BIOPSY:
- Glioblastoma multiforme, WHO grade IV
- B. BRAIN, LEFT OCCIPITAL, EXCISIONAL BIOPSY, NCI #1:
- Glioblastoma multiforme, WHO grade IV
- Up to 5% of tumor necrosis
- Up to 90% of tumor cellularity
- C. BRAIN, LEFT OCCIPITAL, EXCISIONAL BIOPSY, NCI #2:
- Glioblastoma multiforme, WHO grade IV
- Up to 70% of tumor necrosis
- Up to 90% of viable tumor cellularity
- D. BRAIN, LEFT OCCIPITAL, EXCISIONAL BIOPSY, NCI #3:
- Glioblastoma multiforme, WHO grade IV
- Up to 30% of tumor necrosis
- Up to 90% of viable tumor cellularity
- E. BRAIN, LEFT OCCIPITAL EXCISIONAL BIOPSY, NCI #4:
- Glioblastoma multiforme, WHO grade IV
- Up to 30% of tumor necrosis
- Up to 90% of viable tumor cellularity
- F. BRAIN, LEFT OCCIPITAL, EXCISIONAL BIOPSY, NCI #5:
- Glioblastoma multiforme, WHO grade IV
- Up to 1% of tumor necrosis
- Up to 90% of tumor cellularity
- G, H. BRAIN, LEFT OCCIPITAL, EXCISIONAL BIOPSY:
- Glioblastoma multiforme, WHO grade IV

COMMENT: A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar (). Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. . Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Patient Case(s)

[page 2 of 4]
PATIENT: [REDACTED]

PATH #:

Accordingly, elevated expression of beta 1 and focally suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high-grade gliomas [REDACTED]. Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy.

[REDACTED] Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma. [REDACTED]

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case predicts a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with

HISTORY: Neurologic symptoms multiple

MICROSCOPIC:

Sections disclose high-grade infiltrating astrocytic neoplasm composed of pleomorphic hyperchromatic nuclei featuring numerous mitotic figures and associated with florid microvascular proliferation and extensive foci of neutrophil and macrophage-rich abscess-like necrosis with focal palisading.

IMMUNOSTAINS:

MGMT (G1): Up to 5%

PTEN (G1): Retained (2-3+)

pMAPK (G1): Up to 10% of tumor nuclei are positive and up to 60% of tumor cytoplasm is positive

Laminin beta-1 (8/411) (G1): Upregulated (3+ in endothelial cells)

Laminin beta-2 (9/421) (G1): Focal down-regulated (1-2+ in endothelial cells)

EGFR by FISH is pending

GROSS:

A. LEFT FRONTAL

Labeled with the patient's name, labeled "left frontal", and received fresh in the Operating Room for intraoperative frozen consultation and subsequently fixed in formalin is a 2.2 x 1.4 x 0.3 cm aggregate of multiple tan-red soft tissue fragments. Representative portion of tissue was submitted for frozen section analysis.

Entirely embedded.

A1. FSA remnant - multiple

A2. Remaining tissue - 1

B. LEFT OCCIPITAL NCI #1

[page 3 of 4]
PATIENT: [REDACTED]

PATH #:

Labeled with the patient's name, labeled "left occipital NCI #1", and received in a cassette in formalin is a 2.1 x 1.4 x 0.2 cm aggregate of tan-red soft tissue fragments. Entirely embedded.

B1. Multiple

C. LEFT OCCIPITAL NCI #2

Labeled with the patient's name, labeled "left occipital NCI #2", and received fresh and subsequently fixed in formalin in a cassette is a 2.3 x 1.4 x 0.2 cm aggregate of multiple tan-red soft tissue fragments. Entirely embedded.

C1. Multiple

D. LEFT OCCIPITAL NCI #3

Labeled with the patient's name, labeled "left occipital", and received in a cassette labeled "D" are two tan-red soft tissue fragments amounting to 2.1 x 1.2 x 0.2 cm in aggregate. Entirely embedded.

D1. 2

E. LEFT OCCIPITAL NCI #4

Labeled with the patient's name, labeled "B-F left occipital", and received fresh and subsequently fixed in formalin in cassette labeled "E" is a 2.0 x 1.2 x 0.2 cm aggregate of multiple tan-red soft tissue fragments. Entirely embedded.

E1. Multiple

F. LEFT OCCIPITAL NCI #5

Labeled with the patient's name, labeled "D-F left occipital", and received fresh and subsequently fixed in formalin in a cassette labeled "F" are two tan-red soft tissue fragments amounting to 1.5 x 1.1 x 0.3 cm in aggregate. Entirely embedded.

F1. 2

G. LEFT OCCIPITAL PERMANENT

Labeled with the patient's name, labeled "left occipital", and received in formalin is a 6.1 x 3.5 x 1.5 cm aggregate of multiple tan-red friable soft tissue fragments. Entirely embedded.

Slide key:

G1. 3

G2. 5

G3. 1

G4. Multiple

G5. 1

G6. 1

H. LEFT OCCIPITAL

Labeled with the patient's name, labeled "left occipital", and received in formalin are two friable tan-red soft tissue fragments amounting to 3.0 x 2.5 x 1.0 cm in aggregate. The portions of tissue are serially sectioned and entirely embedded.

Slide key:

H1-H3. 2,2,2

Gross dictated by
[REDACTED]

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

OCCIPITAL FS AND TP:

- High-grade glioma

[page 4 of 4]
PATIENT: [REDACTED]

PATH #:

TCGA-28-1751

[REDACTED]

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] and Laboratory Medicine. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed [REDACTED]

Source: NCI Genomic Data Commons file 66ca39f1-23db-4585-8959-5d2c67739915 (TCGA-28-1751.19F9B34F-8FD6-4B0B-B4A5-BDF247570394.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).